Gene-level copy-number profile of tumor specimen TCGA-UB-A7MF-01A from TCGA case TCGA-UB-A7MF, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 57.0 years (20,815 days).
Specimen TCGA-UB-A7MF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.d8dfee82-01d5-4400-9b69-9e71ddbeaa00.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UB-A7MF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1ee38802-966f-4806-9b4b-526d356fa585

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 2: 4,915; copy number 3: 21,810; copy number 4: 27,357; copy number 5: 3,139; copy number 6: 1,701; copy number 7: 173; copy number 9: 51; copy number 11: 667.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UB-A7MF-01A-11D-A33B-01): tumor purity 0.63, ploidy 3.7, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,064,089–181,523,001, 4 genes: LINC00290, AC019235.1, LINC02500, AC093840.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 718 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:79,491,802–83,012,926, 51 genes, copy number 9 (within-gene range 7–9): LINC00989, OR7E94P, AC092542.1, LINC02469, PCAT4, SNORA75, ANTXR2, KPNA2P1, RPSAP39, AC021127.1, PRDM8, FGF5, CFAP299, AC105917.1, BMP3, PRKG2, PRKG2-AS1, RNU5A-2P, RASGEF1B, MTCYBP44, COX5BP1, AC021863.1, NPM1P41, HNRNPA3P13, RNU6-499P, BIN2P1, VAMP9P, AC124016.2, HNRNPD, AC124016.1, IGBP1P4, SNORD42, HNRNPDL, ENOPH1, TMEM150C, RPL7AP26, AC067942.1, AC067942.3, AC067942.2, LINC00575, AC067942.4, SCD5, AC073413.1, MIR575, AC073413.2, SEC31A, THAP9-AS1, THAP9, LIN54, Y_RNA, RNU6-615P.
- chr13:55,062,945–114,337,626, 667 genes, copy number 11 (within-gene range 5–14) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
